Somatic mutation profile of tumor specimen 0DP6I5 from CCDI case PBCDGG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.3 years (4,129 days).
Specimen 0DP6I5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2e31066-f103-46a9-8caa-a43969e0ab7f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP6HL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ee3ce52-5ce6-482d-938f-6e8115eb1b33

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 1, 5'UTR 1, Silent 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/267 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VPS13D | c.6743G>A p.R2248H | Missense Mutation (SNP) | VAF 93/376 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs202191188; called by muse, mutect2, varscan2
- ADAMTS6 | c.3081G>A p.W1027* | Nonsense Mutation (SNP) | VAF 58/319 reads (18%) | called by muse, mutect2, varscan2
- FMR1 | c.104+1G>T p.X35_splice | Splice Site (SNP) | VAF 13/316 reads (4%) | called by muse, mutect2
- MAGI2 | c.3406G>A p.D1136N | Missense Mutation (SNP) | VAF 119/343 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- RGP1 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 22/654 reads (3%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.864); called by muse, mutect2
- NF1 | c.2298T>C p.I766= | Silent (SNP) | VAF 56/181 reads (31%) | called by muse, mutect2, varscan2
- NUP58 | c.-65T>C | 5'UTR (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2
